Somatic mutation profile of tumor specimen TARGET-20-PATDRZ-09A (aliquot TARGET-20-PATDRZ-09A-01D) from TARGET case TARGET-20-PATDRZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.0 years (6,199 days).
Specimen TARGET-20-PATDRZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08a9fcc5-ece5-4ae6-8cbe-7376b7978b45.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDRZ-14A (Bone Marrow Normal), aliquot TARGET-20-PATDRZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b49d4e58-161c-42c9-a09c-c5546b3b944a

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 81/179 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/47 reads (43%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FHDC1 | c.*1057del | 3'UTR (DEL) | VAF 50/120 reads (42%) | called by mutect2, pindel, varscan2
